Somatic mutation profile of tumor specimen TCGA-YL-A8HM-01A (aliquot TCGA-YL-A8HM-01A-11D-A364-08) from TCGA case TCGA-YL-A8HM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,121 days).
Specimen TCGA-YL-A8HM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16926399-941d-47b0-8077-66c8d0e06f7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8HM-10A (Blood Derived Normal), aliquot TCGA-YL-A8HM-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01e5cf4d-ad33-4046-ac79-8db4d7dce41b

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 25, Silent 12, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.260A>C p.Y87S | Missense Mutation (SNP) | VAF 48/94 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP3M1 | c.339A>C p.L113F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786750; called by muse, mutect2, varscan2
- CAD | c.1896A>G p.I632M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99255506; called by muse, mutect2, varscan2
- CCDC172 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.072); catalogued as COSV100319922; called by muse, mutect2
- CD8B | c.338T>G p.I113S | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100514672; called by muse, mutect2, varscan2
- CFH | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.886); catalogued as rs533322868, COSV62776280; called by muse, mutect2, varscan2
- CRACD | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs886146243, COSV99949810; called by muse, mutect2
- ESCO2 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV100533361; called by muse, mutect2, varscan2
- F8 | c.3221dup p.N1074Kfs*13 | Frame Shift Ins (INS) | VAF 40/77 reads (52%) | catalogued as CI124562; called by mutect2, pindel, varscan2
- FAM110C | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs201168179, COSV100566844, COSV100566918; called by muse, mutect2, varscan2
- IL36RN | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100697281, COSV100697291; called by muse, mutect2, varscan2
- INPP5B | c.2952T>G p.F984L (on ENST00000373023; = p.F904L on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100886563; called by muse, varscan2
- KNDC1 | c.4018G>T p.G1340W | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758201955, COSV100465879; called by muse, mutect2, varscan2
- MYH1 | c.4819G>T p.A1607S | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as COSV99876615; called by muse, mutect2, varscan2
- NOB1 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99264046; called by muse, mutect2, varscan2
- OCRL | c.198A>C p.Q66H | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV100843524; called by muse, mutect2, varscan2
- PAK5 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100781582, COSV62037586; called by muse, mutect2, varscan2
- PEX2 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV100824878; called by muse, mutect2, varscan2
- PIWIL1 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99806767; called by muse, mutect2, varscan2
- PIWIL1 | c.2253G>C p.Q751H | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99806769; called by muse, mutect2, varscan2
- S1PR4 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV99859332; called by muse, mutect2, varscan2
- SERPINA9 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.222); catalogued as COSV100098645; called by muse, mutect2, varscan2
- TRPC5 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs867965357, COSV53284596; called by muse, mutect2, varscan2
- VRTN | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs144045913; called by muse, mutect2, varscan2
- ZDHHC5 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs373745864; called by mutect2, varscan2
- ZDHHC5 | c.1533del p.A512Lfs*103 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1358168831; called by mutect2, pindel, varscan2
- ZNF267 | c.620del p.R207Qfs*19 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV56251371; called by mutect2, pindel, varscan2
- ZNF382 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99497998; called by muse, mutect2, varscan2
- ZNF483 | c.1687A>T p.S563C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100493074; called by muse, mutect2, varscan2
- TAB1 | c.1226_1248del p.L409Hfs*42 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ADGRE2 | c.1827C>A p.L609= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- DNAH17 | c.11760C>T p.N3920= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs777605812, COSV67749190; called by muse, mutect2, varscan2
- ETV1 | c.495C>T p.F165= | Silent (SNP) | VAF 93/170 reads (55%) | catalogued as COSV99624245; called by muse, mutect2, varscan2
- HLA-DQA2 | c.642G>A p.E214= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1330673300, COSV100890780; called by muse, varscan2
- KIAA1755 | c.2046C>T p.D682= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs747248434, COSV99642509; called by muse, mutect2, varscan2
- KIF5A | c.2451C>T p.P817= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs976137208, COSV54060816; called by muse, mutect2
- NAXE | c.525G>A p.T175= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs182257927, COSV100576982; called by muse, mutect2, varscan2
- PER2 | c.3222G>T p.S1074= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99612372; called by muse, mutect2, varscan2
- SLC12A6 | c.3291G>A p.K1097= (on ENST00000354181 / NM_001365088.1; = p.K1046= on NM_005135.2) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99273063; called by muse, mutect2, varscan2
- VAV1 | c.2475C>A p.I825= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100409363; called by muse, mutect2
- ZNF646 | c.3108C>T p.L1036= | Silent (SNP) | VAF 69/125 reads (55%) | catalogued as COSV99762551; called by muse, mutect2, varscan2
- ZNF77 | c.948G>A p.R316= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV100094568; called by muse, mutect2, varscan2
